Gene-level copy-number profile of tumor specimen MP2PRT-PANZGJ-TMP1-A from MP2PRT case MP2PRT-PANZGJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,075 days).
Specimen MP2PRT-PANZGJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1dba6fc-7ce0-4b5c-9b42-782e71dcac09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANZGJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,770 have no estimate.
https://portal.gdc.cancer.gov/files/e11a131b-5fd0-465a-bdbc-cd95f1e854b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 3,546; copy number 2: 48,377; copy number 3: 3,485; copy number 4: 2,505; copy number 5: 794; copy number 6: 15.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,252,736, 36 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31.
- chr2:197,197,991–197,199,273, 1 gene (within-gene range 0–2): ANKRD44-AS1.
- chr2:218,382,029–218,405,941, 4 genes: SLC11A1, CTDSP1, AC021016.2, MIR26B.
- chr7:38,239,580–38,378,804, 23 genes: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:50,304,068–50,405,101, 2 genes: IKZF1, AC124014.1.
- chr9:70,384,597–70,414,624, 1 gene: KLF9.
- chr9:97,904,489–97,922,516, 3 genes: TRMO, Y_RNA, AL499604.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–4): TRDD1, TRDD2.
- chr14:105,851,705–106,130,072, 53 genes (within-gene range 0–4): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr15:55,180,806–55,197,049, 1 gene: RSL24D1.
- chr15:63,500,737–63,503,083, 1 gene: AC007950.2.
- chr16:84,565,596–84,618,078, 2 genes: COTL1, AC092145.1.
- chr17:30,830,901–30,831,318, 1 gene: AC127024.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 805 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–2,462,942, 87 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:18,333,726–18,650,966, 17 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr21:10,482,738–33,170,649, 357 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr21:33,584,687–36,016,546, 37 genes, copy number 5 (within-gene range 4–5): AP000311.1, CRYZL1, ITSN1, ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2, SMIM11A, FAM243A, AP000322.2, SMIM34A, AP000322.1, KCNE1, AP000324.1, RCAN1, CLIC6, LINC00160, LINC01426, RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2, LINC01436, RPL23AP3.
- chr21:36,156,782–46,691,226, 307 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
